Somatic mutation profile of tumor specimen C3N-06052-02 (aliquot CPT0439070009) from CPTAC case C3N-06052, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 70.4 years (25,708 days).
Specimen C3N-06052-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54b99aba-355b-438c-bf34-776230d2a161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06052-31 (Blood Derived Normal), aliquot CPT0444880005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6dc9888-1be9-4339-be1e-0da96c718a40

The open-access MAF lists 324 somatic variants for this specimen: 229 protein-altering or splice-affecting, 84 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 84, Nonsense Mutation 12, Intron 7, In Frame Del 3, 5'UTR 2, Splice Region 2, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAJC3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 60/284 reads (21%) | catalogued as rs727502865, CM1413512, COSV65130349; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.3725C>T p.P1242L (on ENST00000272895 / NM_173076.3; = p.P924L on NM_015657.3) | Missense Mutation (SNP) | VAF 84/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770774395; called by muse, mutect2, varscan2
- AP3D1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 90/411 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs769763871; called by muse, mutect2, varscan2
- APOBR | c.3029G>A p.R1010Q (on ENST00000431282; = p.R1019Q on NM_018690.4) | Missense Mutation (SNP) | VAF 98/493 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771510670; called by muse, mutect2, varscan2
- BRCA2 | c.7594C>T p.P2532S | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BST1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as rs758740988, COSV53947883; called by muse, mutect2, varscan2
- C2CD3 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs143645446; called by muse, mutect2, varscan2
- CACNA2D4 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 83/382 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356863731; called by muse, mutect2, varscan2
- CCDC141 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs865980981, COSV55377174; called by muse, mutect2, varscan2
- CCT4 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs1159663207; called by muse, mutect2, varscan2
- CD5L | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 103/493 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV63821845; called by muse, mutect2, varscan2
- CHRNA3 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 121/499 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1392044688, COSV58774673; called by muse, mutect2, varscan2
- CHTF18 | c.1327-1G>A p.X443_splice | Splice Site (SNP) | VAF 81/345 reads (23%) | catalogued as rs1163551641; called by muse, mutect2, varscan2
- CLCN4 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 121/522 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66465197; called by muse, mutect2, varscan2
- COL1A2 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 243/492 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51963799; called by muse, mutect2, varscan2
- COL27A1 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs774595771; called by muse, mutect2, varscan2
- CORIN | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759705913; called by muse, mutect2, varscan2
- CRACD | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 91/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99949265; called by muse, mutect2, varscan2
- CSPG4 | c.6352C>T p.L2118F | Missense Mutation (SNP) | VAF 130/546 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1199724214; called by muse, varscan2
- CYP2C8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV64876038; called by muse, mutect2, varscan2
- DCAF4L2 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 183/682 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150544; called by muse, mutect2, varscan2
- DEUP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 94/448 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99976900; called by muse, mutect2, varscan2
- DHX36 | c.2074C>T p.H692Y | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1362459799; called by muse, mutect2, varscan2
- DSCAM | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68021687; called by muse, mutect2, varscan2
- DYSF | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs200422222, COSV99249487; called by muse, mutect2, varscan2
- EML6 | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs972657970, COSV62872060; called by muse, mutect2, varscan2
- ESS2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 105/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755792682, COSV52817361; called by muse, mutect2, varscan2
- ESS2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 106/417 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749686222; called by muse, mutect2, varscan2
- ETV2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs1458021006; called by muse, mutect2, varscan2
- FAM149B1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs563849642; called by muse, mutect2, varscan2
- FBLIM1 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.424); catalogued as rs144480582, COSV60031517; called by muse, mutect2, varscan2
- FCHSD1 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs764470877; called by muse, mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 103/442 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FGF12 | c.512G>A p.R171Q (on ENST00000454309 / NM_021032.5; = p.R109Q on NM_004113.6) | Missense Mutation (SNP) | VAF 78/408 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218980666, COSV53177549; called by muse, mutect2, varscan2
- FLG | c.9668G>A p.G3223E | Missense Mutation (SNP) | VAF 86/512 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1228150785, COSV64251091; called by muse, mutect2, varscan2
- FLNC | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 190/408 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs753057268; called by muse, mutect2, varscan2
- FMOD | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 98/443 reads (22%) | catalogued as rs1377460558, COSV61610265; called by muse, mutect2, varscan2
- FSIP2 | c.19351C>T p.P6451S | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100555261; called by muse, mutect2, varscan2
- FSTL5 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100056575; called by muse, mutect2, varscan2
- FTSJ1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50025921; called by muse, mutect2, varscan2
- G3BP1 | c.55T>C p.Y19H | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62365656; called by muse, mutect2, varscan2
- GALNT17 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 337/764 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.709); catalogued as rs866308070, COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- GIMAP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 253/522 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs200007879; called by muse, mutect2, varscan2
- GPKOW | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs782276980, COSV50243003; called by muse, mutect2, varscan2
- GPR21 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 97/425 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1451478395, COSV65378891; called by muse, varscan2
- GRIN2A | c.2984C>T p.T995M | Missense Mutation (SNP) | VAF 81/380 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777687136, COSV58031170, COSV58061084; called by muse, mutect2, varscan2
- GRIN2B | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV74206740; called by muse, mutect2, varscan2
- HTR1B | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 94/353 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV100885523; called by muse, mutect2, varscan2
- HYDIN | c.14443G>A p.E4815K | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs868756797, COSV66638408; called by muse, mutect2, varscan2
- HYDIN | c.6605C>T p.T2202I | Missense Mutation (SNP) | VAF 125/536 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV59250365; called by muse, mutect2, varscan2
- IGSF10 | c.3895C>T p.P1299S | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs761343862; called by muse, mutect2, varscan2
- IL37 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200209919; called by muse, mutect2, varscan2
- KCNG4 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 105/406 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs145735728, COSV57584380; called by muse, mutect2, varscan2
- KCNH1 | c.561C>T p.V187= | Splice Region (SNP) | VAF 52/272 reads (19%) | catalogued as COSV55093782; called by muse, mutect2, varscan2
- KCNIP4 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV54842166; called by muse, mutect2, varscan2
- KCNJ1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348507217, CM021619, COSV60662525; called by muse, mutect2, varscan2
- LCE1F | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 112/524 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV100542761; called by muse, varscan2
- LCT | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99928704; called by muse, mutect2, varscan2
- LDB2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58767419, COSV58769782; called by muse, mutect2, varscan2
- LPIN1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 127/551 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs776202108, COSV56770847; called by muse, mutect2, varscan2
- LRP4 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66136908; called by muse, mutect2, varscan2
- LRRC4B | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 148/518 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.096); catalogued as rs1047678199; called by muse, mutect2, varscan2
- MCM9 | c.3263C>T p.S1088F | Missense Mutation (SNP) | VAF 95/479 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.275); catalogued as rs901683620; called by muse, mutect2, varscan2
- MED12L | c.5470G>A p.G1824S | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1233484146, COSV56377412; called by muse, mutect2, varscan2
- METTL1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs372769807; called by muse, mutect2, varscan2
- METTL7B | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 104/490 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs1363716699, COSV57694837; called by muse, mutect2, varscan2
- MLYCD | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 121/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1391542291; called by muse, mutect2, varscan2
- MXRA5 | c.8354G>A p.G2785E | Missense Mutation (SNP) | VAF 144/623 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54245037; called by muse, mutect2, varscan2
- MYH1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56855015; called by muse, mutect2, varscan2
- NXF3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.195); catalogued as rs1308724597, COSV67704376; called by muse, mutect2, varscan2
- OPCML | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 90/379 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs762112565, COSV59430551; called by muse, mutect2, varscan2
- OR4S2 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753301201, COSV56748048; called by muse, mutect2, varscan2
- OR8D2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62488026; called by muse, mutect2, varscan2
- OTOF | c.5216G>A p.W1739* (on ENST00000272371 / NM_194248.3; = p.W972* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 56/360 reads (16%) | catalogued as COSV55524308; called by muse, mutect2, varscan2
- PATL1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs775698734; called by muse, mutect2, varscan2
- PCDH8 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); catalogued as rs1345321666; called by muse, mutect2, varscan2
- PCDHGB5 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 141/623 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53908456; called by muse, mutect2, varscan2
- PCLO | c.6673G>A p.E2225K | Missense Mutation (SNP) | VAF 74/579 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61665165; called by muse, mutect2
- PDHA2 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 110/473 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746879115, COSV54777883; called by muse, mutect2, varscan2
- PIK3C2G | c.4399C>T p.R1467* (on ENST00000676171; = p.R1426* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 67/348 reads (19%) | catalogued as rs372507637, COSV99854243; called by muse, mutect2, varscan2
- PKHD1 | c.9575C>T p.S3192F | Missense Mutation (SNP) | VAF 111/425 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs865811572, COSV61873161; called by muse, mutect2, varscan2
- PLEKHA8 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 79/388 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99322206, COSV99322414; called by muse, mutect2, varscan2
- POTEF | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 149/665 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV100665000; called by muse, varscan2
- PTPRQ | c.1456G>A p.E486K (on ENST00000616559; = p.E444K on NM_001145026.2) | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs1254627421; called by muse, varscan2
- RB1CC1 | c.3082A>C p.I1028L | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50278481; called by muse, mutect2, varscan2
- RIBC2 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV61581212; called by muse, mutect2, varscan2
- RPS6KA3 | c.458_460del p.G153del | In Frame Del (DEL) | VAF 54/297 reads (18%) | catalogued as rs398122813; called by pindel, varscan2
- SCN3A | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 85/294 reads (29%) | catalogued as rs1553535431, COSV51801086; called by muse, mutect2, varscan2
- SDCBP | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 176/711 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs761960405, COSV99486330; called by muse, mutect2, varscan2
- SERPINB7 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 51/178 reads (29%) | catalogued as rs756536402; called by muse, mutect2, varscan2
- SIGLEC1 | c.4801G>A p.E1601K | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.099); catalogued as rs201714787, COSV52463996; called by muse, mutect2, varscan2
- SLC22A16 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57927825; called by muse, mutect2, varscan2
- SLC24A3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 105/503 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs769765422, COSV60118640; called by muse, mutect2, varscan2
- SLC6A14 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 85/326 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147231; called by muse, mutect2, varscan2
- SLC8A3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63520960, COSV63524605; called by muse, mutect2, varscan2
- SLC9A6 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 137/596 reads (23%) | catalogued as COSV65788645; called by muse, mutect2, varscan2
- SLC9C2 | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62947954; called by muse, mutect2, varscan2
- SPTBN5 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 111/441 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs760795482, COSV58018175; called by muse, mutect2, varscan2
- SYT10 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755018918, COSV57344614; called by muse, mutect2, varscan2
- TAS2R16 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 283/647 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771070462, COSV50798888; called by muse, mutect2, varscan2
- TEX45 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100861826; called by muse, mutect2, varscan2
- TMPRSS11B | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV60292800; called by muse, mutect2
- TNRC18 | c.5831C>T p.A1944V | Missense Mutation (SNP) | VAF 133/613 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs757990581; called by muse, mutect2, varscan2
- TRANK1 | c.7627C>T p.R2543C | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as rs779534231, COSV57162068; called by muse, mutect2, varscan2
- TRIM77 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 104/409 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV68066415; called by muse, mutect2, varscan2
- TTN | c.86732G>A p.G28911E (on ENST00000591111; = p.G21487E on NM_003319.4) | Missense Mutation (SNP) | VAF 91/471 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV60158424; called by muse, mutect2, varscan2
- TTN | c.55892C>T p.P18631L (on ENST00000591111; = p.P11207L on NM_003319.4) | Missense Mutation (SNP) | VAF 75/391 reads (19%) | PolyPhen probably damaging (0.999); catalogued as rs760277470, COSV100612870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.11011C>T p.H3671Y (on ENST00000591111; = p.H3625Y on NM_003319.4) | Missense Mutation (SNP) | VAF 85/393 reads (22%) | catalogued as rs749409521; called by muse, mutect2, varscan2
- UGT1A8 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs371007453; called by muse, mutect2, varscan2
- UGT2B15 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV57733144; called by muse, mutect2, varscan2
- XRCC1 | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140655170; called by muse, mutect2, varscan2
- ZFHX4 | c.7012G>A p.D2338N | Missense Mutation (SNP) | VAF 179/668 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51467949; called by muse, mutect2, varscan2
- ZNF233 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100492461; called by muse, mutect2, varscan2
- ZNF835 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1179872097, COSV73379447; called by muse, mutect2, varscan2
- ZSWIM3 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 91/320 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs199802593; called by muse, mutect2, varscan2
- ACHE | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 111/751 reads (15%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3127C>T p.H1043Y | Missense Mutation (SNP) | VAF 95/650 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHDC1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 155/624 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- APAF1 | c.673G>A p.D225N (on ENST00000551964 / NM_181861.2; = p.D214N on NM_001160.3) | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- APOBEC3F | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AQP1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ARHGAP28 | c.592G>A p.E198K (on ENST00000383472 / NM_001366230.1; = p.E39K on NM_001010000.3) | Missense Mutation (SNP) | VAF 104/423 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGEF6 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 84/405 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASXL2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATRNL1 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BANP | c.847C>T p.P283S (on ENST00000286122; = p.P252S on NM_017869.4) | Missense Mutation (SNP) | VAF 74/336 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C11orf95 | c.1237_1239del p.A413del | In Frame Del (DEL) | VAF 155/587 reads (26%) | called by mutect2, pindel, varscan2
- C12orf56 | c.1348G>A p.E450K (on ENST00000543942 / NM_001170633.2; = p.E290K on NM_001099676.3) | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C1QL3 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 204/489 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CAPN13 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 95/397 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- CASP1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 119/610 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CCDC168 | c.18187G>A p.D6063N | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDC42EP1 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.508); called by mutect2, varscan2
- CDH4 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CELF6 | c.991T>A p.S331T | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNB4 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 85/394 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CNTLN | c.2668A>C p.T890P | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTLN | c.2669C>G p.T890R | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP3 | c.2616T>A p.N872K | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COL4A3 | c.2801G>A p.G934E | Missense Mutation (SNP) | VAF 77/437 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CORO2B | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 59/348 reads (17%) | called by muse, mutect2, varscan2
- CPD | c.3392C>T p.P1131L | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE3 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 176/689 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTNNA3 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CYP1A2 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 59/283 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK11 | c.5227C>T p.H1743Y | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- DPT | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 90/389 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L4B | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAAP100 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 141/577 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM217A | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN1 | c.4982G>A p.G1661E | Missense Mutation (SNP) | VAF 107/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC1 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 92/295 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- FSIP2 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 56/279 reads (20%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- FYN | c.533G>C p.S178T | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GAGE10 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GBP7 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GFAP | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 74/329 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GIMAP5 | c.44-1G>A p.X15_splice | Splice Site (SNP) | VAF 147/308 reads (48%) | called by muse, mutect2, varscan2
- GOLGA6C | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); called by mutect2, varscan2
- GOLGA8T | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPCPD1 | c.652A>T p.S218C | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- GPLD1 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 84/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPR179 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 140/629 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HDAC9 | c.2169A>T p.Q723H | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HUWE1 | c.12608A>G p.K4203R | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGLV1-44 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 85/398 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV3-10 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 75/353 reads (21%) | called by muse, mutect2, varscan2
- IL12B | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- KBTBD7 | c.238_240delinsTG p.R80Cfs*10 | Frame Shift Del (DEL) | VAF 54/551 reads (10%) | called by pindel, varscan2*
- KIAA1958 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 100/473 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- KRT84 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LRIG1 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 125/532 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- LRRC3C | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 78/447 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP3K15 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MECOM | c.829G>A p.G277S (on ENST00000468789 / NM_001105078.4; = p.G465S on NM_004991.4) | Missense Mutation (SNP) | VAF 94/405 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC22 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 155/657 reads (24%) | SIFT tolerated, low confidence (0.57); called by muse, mutect2, varscan2
- MYOF | c.5053G>A p.G1685S | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NCSTN | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2
- NECAB1 | c.37_39del p.N13del | In Frame Del (DEL) | VAF 56/522 reads (11%) | called by pindel, varscan2
- NEDD8 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NT5DC2 | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NT5E | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 85/411 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCRL | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 104/412 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- OR13C5 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 63/342 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- OR4C13 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.045); called by muse, varscan2
- OR56A4 | c.989T>A p.L330Q | Missense Mutation (SNP) | VAF 122/471 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR5H8 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- PEAR1 | c.1741A>C p.T581P | Missense Mutation (SNP) | VAF 112/479 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PHF2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3C2G | c.2412T>A p.A804= (on ENST00000676171; = p.A763= on NM_004570.5) | Splice Region (SNP) | VAF 32/217 reads (15%) | called by muse, mutect2, varscan2
- PLXNB1 | c.4730T>C p.F1577S | Missense Mutation (SNP) | VAF 140/415 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAME | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 112/521 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- PTGS2 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP3B | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 117/517 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- QPCT | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- RAPSN | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 96/401 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SAT1 | c.514T>G p.*172Gext*5 | Nonstop Mutation (SNP) | VAF 73/269 reads (27%) | called by muse, mutect2, varscan2
- SDC3 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETDB1 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SH3TC1 | c.3971G>A p.C1324Y | Missense Mutation (SNP) | VAF 132/563 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC4A8 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SLFN14 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 104/425 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SPANXN1 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 77/383 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPEF2 | c.1203dup p.Q402Tfs*4 | Frame Shift Ins (INS) | VAF 47/256 reads (18%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 79/377 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNRG | c.3695C>T p.S1232F | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF1 | c.3940G>A p.D1314N (on ENST00000373790 / NM_138923.4; = p.D1335N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TENM3 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM4 | c.575A>C p.H192P | Missense Mutation (SNP) | VAF 118/568 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- TFAP2C | c.405_419delinsT p.V136Gfs*82 | Frame Shift Del (DEL) | VAF 98/443 reads (22%) | called by pindel, varscan2*
- TMEM108 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 132/534 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TMEM266 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 105/519 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- TP63 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 107/444 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.674); called by muse, mutect2
- TRAF7 | c.363T>A p.F121L | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRIM49C | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TTC24 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTN | c.64925G>A p.G21642E (on ENST00000591111; = p.G14218E on NM_003319.4) | Missense Mutation (SNP) | VAF 104/433 reads (24%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ULK4 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- VAC14 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 92/410 reads (22%) | called by muse, mutect2, varscan2
- VPS13A | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZC3H11B | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ZC3HAV1 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF17 | c.1601T>C p.F534S | Missense Mutation (SNP) | VAF 100/454 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF239 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 112/362 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF292 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 128/489 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF492 | c.1481G>A p.R494K | Missense Mutation (SNP) | VAF 85/363 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.78C>T p.F26= | Silent (SNP) | VAF 62/246 reads (25%) | catalogued as rs1209829567, COSV70043386; called by muse, mutect2, varscan2
- ABCC3 | c.639C>T p.G213= | Silent (SNP) | VAF 68/380 reads (18%) | called by muse, mutect2, varscan2
- ABHD2 | c.534C>A p.T178= | Silent (SNP) | VAF 66/247 reads (27%) | called by mutect2, varscan2
- AC244197.3 | c.501C>T p.F167= | Silent (SNP) | VAF 118/544 reads (22%) | called by muse, mutect2, varscan2
- AHDC1 | c.3427C>T p.L1143= | Silent (SNP) | VAF 95/390 reads (24%) | catalogued as rs760179924, COSV99899421; called by muse, mutect2, varscan2
- AIFM3 | c.451C>T p.L151= | Silent (SNP) | VAF 82/383 reads (21%) | catalogued as rs879912043; called by muse, mutect2, varscan2
- AL669918.1 | c.2325C>T p.V775= | Silent (SNP) | VAF 186/760 reads (24%) | called by muse, mutect2, varscan2
- ALMS1 | c.10314C>T p.I3438= | Silent (SNP) | VAF 97/455 reads (21%) | catalogued as rs758270382, COSV100044144; called by muse, mutect2, varscan2
- ANKRD50 | c.1773C>T p.T591= | Silent (SNP) | VAF 90/392 reads (23%) | called by muse, mutect2, varscan2
- APOBR | c.3030G>A p.R1010= (on ENST00000431282; = p.R1019= on NM_018690.4) | Silent (SNP) | VAF 98/496 reads (20%) | catalogued as rs1373855719; called by muse, mutect2, varscan2
- ARHGAP44 | c.804C>T p.I268= | Silent (SNP) | VAF 108/501 reads (22%) | catalogued as rs766941988, COSV52391992; called by muse, mutect2, varscan2
- CABS1 | c.120T>C p.T40= | Silent (SNP) | VAF 100/412 reads (24%) | catalogued as rs1249733643; called by muse, mutect2, varscan2
- CCDC178 | c.417A>T p.V139= | Silent (SNP) | VAF 69/292 reads (24%) | called by muse, mutect2, varscan2
- CDH18 | c.180C>T p.F60= | Silent (SNP) | VAF 75/412 reads (18%) | catalogued as COSV56907828, COSV56940360; called by muse, mutect2, varscan2
- COL4A2 | c.3423C>T p.V1141= | Silent (SNP) | VAF 77/322 reads (24%) | called by muse, mutect2, varscan2
- COL6A5 | c.5373G>A p.R1791= (on ENST00000312481; = p.R1787= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/309 reads (23%) | called by muse, mutect2, varscan2
- COL7A1 | c.6816G>A p.G2272= | Silent (SNP) | VAF 77/364 reads (21%) | called by muse, mutect2, varscan2
- COLCA2 | c.378C>T p.S126= | Silent (SNP) | VAF 78/411 reads (19%) | catalogued as rs1202219389; called by muse, mutect2, varscan2
- CPZ | c.1359G>A p.T453= (on ENST00000360986 / NM_001014447.3; = p.T442= on NM_003652.3) | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs374250963; called by muse, mutect2, varscan2
- CSPG4 | c.6351C>T p.D2117= | Silent (SNP) | VAF 132/546 reads (24%) | called by muse, varscan2
- CTRL | c.445C>T p.L149= | Silent (SNP) | VAF 101/448 reads (23%) | called by muse, mutect2, varscan2
- DNAH9 | c.447G>A p.K149= | Silent (SNP) | VAF 105/426 reads (25%) | called by muse, mutect2, varscan2
- DOCK2 | c.474C>T p.I158= | Silent (SNP) | VAF 58/216 reads (27%) | called by muse, mutect2, varscan2
- DRGX | c.198C>T p.L66= | Silent (SNP) | VAF 79/278 reads (28%) | catalogued as rs868359215; called by muse, mutect2, varscan2
- DRP2 | c.2610G>A p.L870= | Silent (SNP) | VAF 106/408 reads (26%) | catalogued as rs1357930314; called by muse, mutect2, varscan2
- EP400 | c.4680C>T p.A1560= | Silent (SNP) | VAF 79/411 reads (19%) | catalogued as rs922929677; called by muse, mutect2, varscan2
- ERAS | c.387C>T p.I129= | Silent (SNP) | VAF 172/700 reads (25%) | catalogued as COSV54432672; called by muse, mutect2, varscan2
- EXPH5 | c.1164C>T p.F388= | Silent (SNP) | VAF 98/459 reads (21%) | catalogued as rs1177163933; called by muse, mutect2, varscan2
- FAM170A | c.156T>G p.T52= | Silent (SNP) | VAF 115/448 reads (26%) | called by muse, mutect2, varscan2
- FBXL7 | c.1344C>T p.I448= | Silent (SNP) | VAF 91/380 reads (24%) | catalogued as rs772413376, COSV61645391; called by muse, mutect2, varscan2
- FRK | c.1089T>G p.G363= | Silent (SNP) | VAF 69/349 reads (20%) | catalogued as rs1441218272; called by muse, mutect2, varscan2
- FTSJ1 | c.558G>A p.R186= | Silent (SNP) | VAF 101/475 reads (21%) | called by muse, mutect2, varscan2
- GPR27 | c.216C>T p.L72= | Silent (SNP) | VAF 115/386 reads (30%) | called by muse, mutect2, varscan2
- HNRNPA1P48 | c.531C>T p.F177= | Silent (SNP) | VAF 99/508 reads (19%) | called by muse, varscan2
- HTR2C | c.984C>T p.F328= | Silent (SNP) | VAF 128/538 reads (24%) | catalogued as COSV52202532; called by muse, mutect2, varscan2
- HYDIN | c.9228G>A p.G3076= | Silent (SNP) | VAF 47/275 reads (17%) | catalogued as rs1460691660, COSV99993790; called by muse, mutect2, varscan2
- KDM4B | c.1611G>A p.K537= | Silent (SNP) | VAF 130/516 reads (25%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1794G>A p.T598= | Silent (SNP) | VAF 98/471 reads (21%) | catalogued as rs747500137, COSV61728064; called by muse, mutect2, varscan2
- KIF4A | c.1560G>A p.A520= | Silent (SNP) | VAF 114/487 reads (23%) | catalogued as rs754387866, COSV65543267; called by muse, mutect2, varscan2
- LHCGR | c.255C>T p.S85= | Silent (SNP) | VAF 52/328 reads (16%) | called by muse, mutect2, varscan2
- METTL2B | c.1086G>T p.R362= | Silent (SNP) | VAF 109/720 reads (15%) | called by muse, mutect2, varscan2
- MFSD2A | c.444C>T p.F148= (on ENST00000372809 / NM_001136493.3; = p.F135= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 86/426 reads (20%) | catalogued as rs748531172; called by muse, mutect2, varscan2
- MLC1 | c.630C>T p.V210= | Silent (SNP) | VAF 80/387 reads (21%) | called by muse, mutect2, varscan2
- MYLK | c.156C>T p.F52= | Silent (SNP) | VAF 56/276 reads (20%) | catalogued as rs200095645, COSV60604762; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO1F | c.648G>A p.G216= | Silent (SNP) | VAF 75/288 reads (26%) | called by muse, mutect2, varscan2
- NDN | c.513G>T p.L171= | Silent (SNP) | VAF 103/440 reads (23%) | called by muse, mutect2, varscan2
- NEB | c.1869C>T p.S623= | Silent (SNP) | VAF 51/315 reads (16%) | catalogued as COSV51428599, COSV99425858; called by muse, mutect2, varscan2
- NEUROG1 | c.639C>A p.G213= | Silent (SNP) | VAF 123/512 reads (24%) | catalogued as COSV59082128; called by muse, mutect2, varscan2
- NF1 | c.6603C>T p.S2201= (on ENST00000358273 / NM_001042492.3; = p.S2180= on NM_000267.3) | Silent (SNP) | VAF 73/303 reads (24%) | called by muse, mutect2, varscan2
- NOL11 | c.1065C>T p.V355= | Silent (SNP) | VAF 76/295 reads (26%) | catalogued as rs774082085; called by muse, mutect2, varscan2
- NUP205 | c.5673C>T p.S1891= | Silent (SNP) | VAF 60/440 reads (14%) | called by muse, mutect2
- NUTM2B | c.492C>T p.L164= | Silent (SNP) | VAF 89/684 reads (13%) | called by muse, mutect2, varscan2
- OBSL1 | c.2430C>T p.D810= | Silent (SNP) | VAF 70/331 reads (21%) | catalogued as COSV54708135; called by muse, mutect2, varscan2
- OR2F2 | c.144G>A p.L48= | Silent (SNP) | VAF 108/752 reads (14%) | catalogued as rs760490723; called by muse, mutect2, varscan2
- OR2G2 | c.774C>T p.I258= | Silent (SNP) | VAF 98/436 reads (22%) | catalogued as rs865888004; called by muse, mutect2, varscan2
- OSCAR | c.234C>T p.L78= | Silent (SNP) | VAF 114/588 reads (19%) | catalogued as rs1316180765, COSV52927716, COSV99499782; called by muse, mutect2, varscan2
- PANX2 | c.885C>T p.I295= | Silent (SNP) | VAF 133/584 reads (23%) | catalogued as rs1454228104; called by muse, mutect2, varscan2
- PCDH15 | c.978C>T p.I326= | Silent (SNP) | VAF 36/193 reads (19%) | catalogued as rs563269633, COSV57398868; called by muse, mutect2, varscan2
- PCDHB7 | c.2343G>A p.V781= | Silent (SNP) | VAF 50/694 reads (7%) | called by muse, mutect2
- PCSK7 | c.1926C>T p.F642= | Silent (SNP) | VAF 28/266 reads (11%) | catalogued as rs1387888010, COSV54062908; called by muse, mutect2
- PDZRN3 | c.1914C>T p.I638= | Silent (SNP) | VAF 120/478 reads (25%) | catalogued as rs374714693; called by muse, mutect2, varscan2
- PHF24 | c.870G>A p.L290= | Silent (SNP) | VAF 92/429 reads (21%) | catalogued as rs1328672761; called by muse, mutect2, varscan2
- PLSCR3 | c.639C>T p.T213= | Silent (SNP) | VAF 88/368 reads (24%) | called by muse, mutect2, varscan2
- PPP3CA | c.618T>A p.I206= | Silent (SNP) | VAF 48/240 reads (20%) | catalogued as rs769123247; called by muse, mutect2, varscan2
- PSG11 | c.747C>T p.T249= | Silent (SNP) | VAF 84/372 reads (23%) | catalogued as rs746588679, COSV60454064; called by muse, mutect2
- QARS1 | c.783T>G p.G261= | Silent (SNP) | VAF 89/349 reads (26%) | called by muse, mutect2, varscan2
- RANBP17 | c.3148C>T p.L1050= | Silent (SNP) | VAF 50/223 reads (22%) | catalogued as COSV101206259; called by muse, mutect2, varscan2
- RGL3 | c.447C>T p.G149= | Silent (SNP) | VAF 80/373 reads (21%) | called by muse, mutect2, varscan2
- RP1 | c.3555T>A p.P1185= | Silent (SNP) | VAF 65/538 reads (12%) | called by muse, mutect2, varscan2
- RPUSD1 | c.651G>A p.T217= | Silent (SNP) | VAF 136/593 reads (23%) | catalogued as rs765115586; called by muse, mutect2, varscan2
- SALL3 | c.1518G>A p.E506= | Silent (SNP) | VAF 162/562 reads (29%) | called by muse, mutect2, varscan2
- SIGLECL1 | c.87C>T p.F29= | Silent (SNP) | VAF 95/415 reads (23%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1107C>T p.I369= | Silent (SNP) | VAF 100/494 reads (20%) | called by muse, mutect2, varscan2
- STARD9 | c.5355C>T p.N1785= | Silent (SNP) | VAF 94/453 reads (21%) | called by muse, mutect2, varscan2
- STK11 | c.882G>T p.P294= | Silent (SNP) | VAF 90/438 reads (21%) | catalogued as COSV58819962; called by muse, mutect2, varscan2
- TBC1D31 | c.249A>C p.A83= | Silent (SNP) | VAF 325/578 reads (56%) | called by muse, mutect2, varscan2
- TOX | c.345C>T p.L115= | Silent (SNP) | VAF 84/707 reads (12%) | catalogued as rs373033791; called by muse, mutect2, varscan2
- TTC24 | c.774C>T p.A258= | Silent (SNP) | VAF 94/485 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.12954G>A p.V4318= (on ENST00000591111; = p.V4272= on NM_003319.4) | Silent (SNP) | VAF 82/377 reads (22%) | catalogued as COSV100626653, COSV59913413; called by muse, mutect2, varscan2
- USP26 | c.2112C>A p.T704= | Silent (SNP) | VAF 110/455 reads (24%) | called by muse, mutect2, varscan2
- VPS29 | c.531C>T p.I177= | Silent (SNP) | VAF 60/331 reads (18%) | catalogued as rs374307546; called by muse, mutect2, varscan2
- VSIG4 | c.912C>T p.I304= | Silent (SNP) | VAF 101/442 reads (23%) | called by muse, mutect2, varscan2
- ZNF711 | c.1737C>T p.R579= | Silent (SNP) | VAF 109/475 reads (23%) | called by muse, mutect2, varscan2
- ZNF717 | c.846C>T p.P282= | Silent (SNP) | VAF 86/474 reads (18%) | called by muse, varscan2
- AL353804.4 | chrX:73821080 C>T | 3'Flank (SNP) | VAF 72/316 reads (23%) | called by muse, mutect2, varscan2
- ANK3 | c.12596-331C>T | Intron (SNP) | VAF 55/227 reads (24%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+1279C>A | Intron (SNP) | VAF 155/598 reads (26%) | called by muse, mutect2, varscan2
- CCDC141 | c.1899+38G>A | Intron (SNP) | VAF 69/273 reads (25%) | catalogued as COSV99837165; called by muse, mutect2, varscan2
- DNALI1 | c.-1C>T | 5'UTR (SNP) | VAF 68/232 reads (29%) | catalogued as rs1029855525; called by muse, varscan2
- MAGI2 | c.2047+49G>A | Intron (SNP) | VAF 198/450 reads (44%) | called by muse, mutect2, varscan2
- NGEF | c.384-792T>C | Intron (SNP) | VAF 65/313 reads (21%) | called by muse, mutect2, varscan2
- NPAP1L | n.48C>T | RNA (SNP) | VAF 51/242 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.34264+584C>T | Intron (SNP) | VAF 48/267 reads (18%) | catalogued as rs375507473, COSV60180893; called by muse, mutect2, varscan2
- TTN | c.10360+1384G>A | Intron (SNP) | VAF 97/407 reads (24%) | called by muse, mutect2, varscan2
- WRAP53 | c.-1083C>T | 5'UTR (SNP) | VAF 81/338 reads (24%) | catalogued as rs1319632861; called by muse, mutect2, varscan2
